Somatic mutation profile of tumor specimen 0DPUTL from CCDI case PBCEAP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.6 years (4,241 days).
Specimen 0DPUTL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1adb170a-6f63-494a-ba3a-5b2e6ca22bf0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPUTH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31ae7d9e-bd6e-4a67-ba34-9b27e8ce67ff

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Frame Shift Del 2, Intron 2, Splice Region 1, 3'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 208/502 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 42/56 reads (75%) | catalogued as rs768244116; called by mutect2, varscan2
- CCDC168 | c.16315C>A p.L5439I | Missense Mutation (SNP) | VAF 14/430 reads (3%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.801); catalogued as rs1378373417; called by muse, mutect2
- EPHA3 | c.251C>G p.T84R | Missense Mutation (SNP) | VAF 70/272 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60717916; called by muse, mutect2, varscan2
- MYH6 | c.5257G>C p.A1753P | Missense Mutation (SNP) | VAF 63/164 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142437308; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR7G2 | c.968G>C p.R323T | Missense Mutation (SNP) | VAF 129/309 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV104398849; called by muse, mutect2, varscan2
- HERPUD2 | c.513del p.P172Lfs*58 | Frame Shift Del (DEL) | VAF 42/304 reads (14%) | called by mutect2, varscan2
- ITGA8 | c.1191C>A p.N397K | Missense Mutation (SNP) | VAF 88/236 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- POP5 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 69/218 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- THSD7B | c.4656A>C p.P1552= (on ENST00000272643; = p.P1550= on NM_001316349.2) | Splice Region (SNP) | VAF 51/179 reads (28%) | called by muse, mutect2, varscan2
- USP43 | c.217G>T p.G73W | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.065); called by muse, mutect2
- SLTM | c.2253A>G p.T751= | Silent (SNP) | VAF 14/313 reads (4%) | catalogued as rs1165028781; called by muse, mutect2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 10/268 reads (4%) | called by muse, mutect2
- SIK3 | c.3635+74dup | Intron (INS) | VAF 7/21 reads (33%) | called by mutect2, varscan2
- SPG7 | c.1642+52del | Intron (DEL) | VAF 4/40 reads (10%) | called by mutect2, varscan2
